Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6512, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6512-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Total organ resection – colon and rectum

TCGA – EI – 6512

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the rectosigmoid junction

Examination performed on:

Macroscopic description:

17 cm length of the large intestine with periintestinal tissue sized 2.5 x 15 x 8 cm. Cauliflower-shaped ulcerous tumour sized 6 x 6 x 1 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference, located 5 cm from one of the excision lines and 5 cm from the opposite one.

Microscopic description:

Adenocarcinoma tubulare (G2). Infiltratio carcinomatosa telae adiposae pericolicae.

Intestine ends free of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (No I/XVII).

Histopathological diagnosis:

Adenocarcinoma tubulare coli. Tubulopapillar adenocarcinoma of the colon

Metastases carcinomatosae in lymphonodis (No I/XVII). Cancer metastases in the lymph nodes (No I/XVII)

(G2, Dukes C, Astler-Collier C2, pT3, pN1).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file fd62270e-7d4a-4165-9df4-1e8a11cbb0b2 (TCGA-EI-6512.19ED1EE7-0C19-43C6-8635-59118015420C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).